Somatic mutation profile of tumor specimen TCGA-DX-AATS-01A (aliquot TCGA-DX-AATS-01A-12D-A417-09) from TCGA case TCGA-DX-AATS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 72.9 years (26,624 days).
Specimen TCGA-DX-AATS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e836921-303d-427e-84d1-0d6837cd4cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AATS-10A (Blood Derived Normal), aliquot TCGA-DX-AATS-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdfce9c6-af86-4ad0-8d5d-853868ad7af4

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Nonsense Mutation 5, Splice Site 3, Intron 2, Splice Region 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV100252152; called by muse, mutect2, varscan2
- ADAMTS20 | c.3467G>T p.W1156L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166065; called by muse, mutect2, varscan2
- ALX4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368050443; called by muse, mutect2, varscan2
- APOBEC3F | c.171G>A p.Q57= | Splice Region (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100415098; called by muse, mutect2
- ARHGAP22 | c.2037G>C p.E679D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs1313243217, COSV99984431; called by muse, mutect2, varscan2
- ARHGEF28 | c.3602C>T p.S1201F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99708124; called by muse, mutect2, varscan2
- ASIC4 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100761550; called by muse, mutect2, varscan2
- C5 | c.3842G>T p.G1281V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56331874, COSV99797084; called by muse, mutect2
- CASR | c.1915C>T p.R639C (on ENST00000490131; = p.R716C on NM_000388.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs768333005, COSV56135263; called by muse, varscan2
- CENPM | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99317774; called by muse, mutect2
- CFAP52 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs764423806, COSV55347323; called by muse, mutect2, varscan2
- CFTR | c.233T>C p.F78S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.224); catalogued as CD983595, COSV99133978; called by muse, mutect2, varscan2
- CHST10 | c.100+1G>C p.X34_splice | Splice Site (SNP) | VAF 18/21 reads (86%) | catalogued as COSV99958676; called by muse, mutect2, varscan2
- CNOT10 | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 81/85 reads (95%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs751346626, COSV100093983; called by muse, mutect2, varscan2
- COQ3 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV99632459; called by muse, mutect2, varscan2
- CSMD3 | c.7749G>T p.Q2583H (on ENST00000297405 / NM_001363185.1; = p.Q2479H on NM_052900.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV52210194; called by muse, mutect2, varscan2
- CSN2 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.175); catalogued as COSV61992460; called by muse, mutect2, varscan2
- DLK1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs767836232, COSV57991140; called by muse, mutect2, varscan2
- DPY19L2 | c.2054T>A p.V685E | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100192738, COSV61040319; called by muse, mutect2
- ERN2 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99890545; called by muse, mutect2, varscan2
- FAAP24 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99578793; called by muse, mutect2, varscan2
- FAT3 | c.7387C>A p.P2463T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV99961718; called by muse, mutect2, varscan2
- FBXO15 | c.333-2A>T p.X111_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99503022; called by muse, mutect2, varscan2
- HSPG2 | c.2305C>A p.H769N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101020394; called by muse, mutect2, varscan2
- IRAK3 | c.317-2A>T p.X106_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99705877; called by muse, mutect2, varscan2
- IRX2 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1432721884, COSV57412814; called by muse, mutect2, varscan2
- ITGA10 | c.3489G>C p.E1163D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100994693, COSV65196676; called by muse, mutect2, varscan2
- KCNQ5 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771827882, COSV59651595; called by muse, mutect2, varscan2
- LRBA | c.6607C>T p.R2203C | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs200164280, COSV100840905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.25127C>A p.P8376H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV101198074; called by muse, mutect2, varscan2
- NME9 | c.742G>A p.V248I (on ENST00000333911 / NM_001349024.2; = p.V187I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs763521362, COSV58616800; called by muse, mutect2, varscan2
- NPAP1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.282); catalogued as rs773600317, COSV61504502; called by muse, varscan2
- NPAP1 | c.336T>A p.S112R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs749472971, COSV100274756; called by mutect2, varscan2
- NPHS1 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100799592; called by muse, mutect2, varscan2
- OR10G2 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101606932; called by muse, mutect2, varscan2
- OR8S1 | c.888G>A p.K296= | Splice Region (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100043449, COSV59601001; called by muse, mutect2, varscan2
- PAXBP1 | c.2626A>T p.R876* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99268995; called by muse, mutect2, varscan2
- PCDHB2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV52031934, COSV52032200, COSV99522790; called by muse, mutect2, varscan2
- PMS2 | c.991T>A p.C331S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV99763866; called by muse, mutect2, varscan2
- PRSS53 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99762009; called by muse, mutect2, varscan2
- PTPRG | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99872790; called by muse, mutect2, varscan2
- RALGAPA2 | c.627C>A p.C209* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as COSV99173132; called by muse, mutect2, varscan2
- ROBO3 | c.2902C>T p.H968Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs1259399379, COSV101184902; called by muse, mutect2, varscan2
- SLAMF1 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99348915; called by muse, mutect2, varscan2
- SLC25A13 | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99673033; called by muse, mutect2, varscan2
- SLIT3 | c.2449C>A p.H817N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.244); catalogued as COSV100265328; called by muse, mutect2
- SMPD3 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750468999, COSV54712799; called by muse, mutect2, varscan2
- SND1 | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100689672; called by muse, mutect2, varscan2
- SRRM4 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs114691929; called by muse, mutect2
- SULT1A1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131542; called by muse, mutect2, varscan2
- TFAP2D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99145681; called by muse, mutect2, varscan2
- TRPM1 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99855289; called by muse, mutect2, varscan2
- TSNARE1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as rs373787442; called by muse, mutect2, varscan2
- VWF | c.5374G>T p.A1792S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV54611032, COSV99777919; called by muse, mutect2, varscan2
- ZBTB18 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100699982, COSV100700129; called by muse, mutect2, varscan2
- ZNF257 | c.1335C>A p.Y445* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101448010; called by muse, mutect2, varscan2
- ZNF419 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV99691783; called by muse, mutect2, varscan2
- ZNF615 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV100943712; called by muse, mutect2, varscan2
- ACACA | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATRX | c.1329_1350del p.R444Lfs*19 | Frame Shift Del (DEL) | VAF 15/21 reads (71%) | called by mutect2, varscan2
- IGHV3-66 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- ZNF234 | c.967_970del p.K323Vfs*88 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.4035A>G p.E1345= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100255744; called by muse, mutect2, varscan2
- FAT2 | c.4071G>C p.T1357= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99941624; called by muse, mutect2, varscan2
- FSIP1 | c.1605C>A p.P535= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100617947; called by muse, mutect2
- GPR174 | c.840T>C p.L280= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV99337946; called by muse, mutect2, varscan2
- GPR82 | c.594C>A p.I198= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100220483; called by muse, mutect2, varscan2
- HERC2 | c.12006T>G p.A4002= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- ITIH6 | c.1056T>C p.H352= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99512815; called by muse, mutect2
- MRGPRX1 | c.39A>C p.T13= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100245839; called by muse, mutect2
- MSH5 | c.1854G>A p.V618= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100991722; called by muse, mutect2, varscan2
- MYOM2 | c.1743T>C p.Y581= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs777461483, COSV100036586; called by muse, mutect2, varscan2
- OR4N2 | c.555C>T p.I185= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV60054145, COSV60054822; called by muse, mutect2
- PCDHAC1 | c.1224C>A p.I408= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53839221, COSV99164991; called by muse, mutect2, varscan2
- PRR22 | c.786C>T p.A262= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100287863; called by muse, mutect2, varscan2
- SLC44A1 | c.696A>T p.I232= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100570183; called by muse, mutect2, varscan2
- SYCP2L | c.1785G>A p.L595= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99304641; called by muse, mutect2, varscan2
- TRBV20-1 | c.105C>T p.I35= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs780750911; called by muse, mutect2, varscan2
- TUBAL3 | c.1218C>T p.Y406= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs367579573; called by muse, mutect2, varscan2
- USF3 | c.720C>T p.P240= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs373412362, COSV100324704; called by muse, mutect2
- YAF2 | c.255A>G p.E85= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100586166; called by muse, mutect2, varscan2
- HDAC9 | c.2577+59C>T | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SCARB1 | c.1651+3340G>A | Intron (SNP) | VAF 64/104 reads (62%) | catalogued as rs746306162, COSV99908787; called by muse, mutect2, varscan2
